Somatic mutation profile of tumor specimen MP2PRT-PAVUNV-TMP1-A (aliquot MP2PRT-PAVUNV-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVUNV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,106 days).
Specimen MP2PRT-PAVUNV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2b6b85c-0d5a-41f2-99c8-51c545dd7c0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUNV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUNV-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b69b6a61-9db6-46aa-a214-e9d9c3646ed7

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 7 silent.
By variant classification: Silent 7, Missense Mutation 6, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.277G>C p.A93P | Missense Mutation (SNP) | VAF 282/915 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99537475; called by muse, mutect2, varscan2
- ANO4 | c.1021C>T p.R341W (on ENST00000392977 / NM_001286615.2; = p.R306W on NM_178826.4) | Missense Mutation (SNP) | VAF 126/251 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs771044930; called by muse, mutect2, varscan2
- ARSH | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 138/361 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs757726624, COSV66962934; called by muse, mutect2, varscan2
- MAP1B | c.6053C>T p.P2018L | Missense Mutation (SNP) | VAF 161/319 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1188251248; called by muse, mutect2, varscan2
- IGHJ2 | c.1_2insCCGGGGGG p.Y1Sfs*? | Frame Shift Ins (INS) | VAF 127/160 reads (79%) | called by mutect2, pindel*, varscan2
- IGLV1-44 | c.70A>T p.T24S | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, varscan2
- OR6C75 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 129/295 reads (44%) | called by muse, mutect2, varscan2
- SLC7A11 | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADAM23 | c.1806C>T p.G602= | Silent (SNP) | VAF 148/280 reads (53%) | catalogued as rs893553568; called by muse, mutect2, varscan2
- ANGPTL4 | c.63G>A p.L21= | Silent (SNP) | VAF 321/678 reads (47%) | called by muse, mutect2, varscan2
- CSNK1E | c.783C>T p.D261= | Silent (SNP) | VAF 25/367 reads (7%) | catalogued as rs573293393; called by muse, mutect2
- CTNNA2 | c.312G>A p.R104= | Silent (SNP) | VAF 14/338 reads (4%) | catalogued as COSV63578809; called by muse, mutect2
- KIF4A | c.108C>G p.P36= | Silent (SNP) | VAF 37/454 reads (8%) | called by muse, mutect2
- MUC16 | c.8229G>A p.S2743= | Silent (SNP) | VAF 120/242 reads (50%) | catalogued as COSV101198441, COSV67443037; called by muse, mutect2, varscan2
- PLXNA3 | c.4167C>T p.D1389= | Silent (SNP) | VAF 262/591 reads (44%) | catalogued as rs1557208270; called by muse, mutect2, varscan2
